TCGA case TCGA-F5-6863 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/72e640f2-869f-4aef-8ebe-b127f3e7048a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 71 years; Vital status: Dead; Days to death: 361 days.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 71.0 years (25,936 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 361 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 6; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil + Leucovorin; Days to treatment start: 196 days; Days to treatment end: 251 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 261 days; Days to treatment end: 289 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 71.5 years (26,127 days); Days to diagnosis: 191 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 191 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 361 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 23.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 166 cm; BMI: 27.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-F5-6863-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 1.2; Shortest dimension: 0.8.
  Slide TCGA-F5-6863-01A-01-BS1: Section location: Bottom; Percent tumor cells: 81; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 15.
  Slide TCGA-F5-6863-01A-01-TS1: Section location: Top; Percent tumor cells: 81; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 15.
- Sample TCGA-F5-6863-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-F5-6863-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Drug treatment 4: Pharmaceutical therapy drug name: Xeloda; Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 361 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 361 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 191 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-F5-6863-01A-11D-1923-01): tumor purity 0.75, ploidy 2.32, whole-genome doublings 0.
